Gene-level copy-number profile of tumor specimen CDDP-ACQA-TTP1-A from CDDP_EAGLE case CDDP-ACQA, project CDDP_EAGLE-1: CDDP Integrative Analysis of Lung Adenocarcinoma (Phase 2). Sex at birth: male; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 66 years.
Specimen CDDP-ACQA-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 92e603a2-3ffc-4fda-af94-b7b77b453468.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator CDDP-ACQA-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,845 have no estimate.
https://portal.gdc.cancer.gov/files/cdbca29e-b7a2-4751-976d-794667f440f7

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 1: 542; copy number 2: 2,045; copy number 3: 12,474; copy number 4: 26,393; copy number 5: 11,290; copy number 6: 3,253; copy number 7: 1,781; copy number 8: 625; copy number 9: 144; copy number 10: 173; copy number 11: 25; copy number 12: 9; copy number 13: 3; copy number 14: 5; copy number 15: 11; copy number 19: 1; copy number 21: 3; copy number 52: 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 375 genes in 68 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:149,345,661–149,556,361, 4 genes, copy number 15: SEC22B2P, NOTCH2NLC, AC242842.3, NBPF19.
- chr1:149,887,890–149,936,879, 4 genes, copy number 9 (within-gene range 5–9): BOLA1, SV2A, SF3B4, MTMR11.
- chr1:150,293,861–151,372,707, 61 genes, copy number 10 (broad region; genes not listed).
- chr1:153,606,886–153,726,353, 14 genes, copy number 9: S100A16, S100A14, S100A13, AL162258.1, S100A1, AL162258.2, CHTOP, SNAPIN, ILF2, NPR1, MIR8083, RN7SL372P, GEMIN2P1, Y_RNA.
- chr1:153,947,669–154,271,510, 23 genes, copy number 10 (within-gene range 7–10): CRTC2, SLC39A1, AL358472.7, MIR6737, AL358472.4, AL358472.3, CREB3L4, JTB, AL358472.6, AL358472.2, RAB13, RPS27, NUP210L, AL358472.1, RNU6-179P, RPS7P2, MIR5698, TPM3, RN7SL431P, MIR190B, C1orf189, C1orf43, UBAP2L.
- chr1:154,288,460–154,379,273, 9 genes, copy number 9–15: AL354980.1, RNU6-239P, RNU6-121P, AL354980.2, AQP10, ATP8B2, RNU7-57P, AL162591.1, RPSAP17.
- chr1:155,213,821–155,434,262, 16 genes, copy number 11 (within-gene range 8–11): GBAP1, MTX1P1, GBA, FAM189B, SCAMP3, CLK2, HCN3, PKLR, FDPS, RUSC1-AS1, RUSC1, MIR555, RNU6-106P, ASH1L-IT1, RNU6-1297P, POU5F1P4.
- chr1:155,687,960–155,885,199, 6 genes, copy number 9–11 (within-gene range 8–11): DAP3, AL162734.1, MSTO2P, GON4L, AL139128.1, SYT11.
- chr1:156,082,573–156,248,117, 8 genes, copy number 9–12: LMNA, SEMA4A, AL135927.1, SLC25A44, PMF1-BGLAP, PMF1, BGLAP, PAQR6.
- chr5:10,275,875–10,343,131, 4 genes, copy number 10–14: CMBL, Y_RNA, Y_RNA, AC012640.5.
- chr5:14,872,332–14,877,919, 3 genes, copy number 9: AC016575.1, UQCRBP3, HNRNPKP5.
- chr5:16,661,907–17,276,843, 10 genes, copy number 9–10 (within-gene range 8–10): MYO10, RNA5SP179, RPS26P28, RNU6-660P, BASP1, BASP1-AS1, AC026790.1, Y_RNA, RNA5SP180, DCAF13P2.
- chr5:18,886,622–18,958,413, 4 genes, copy number 9: UBE2V1P12, AC025768.1, AC114981.1, Metazoa_SRP.
- chr5:31,532,287–32,444,740, 29 genes, copy number 9–10: C5orf22, AC022417.1, RNU6-363P, PDZD2, AC022447.2, AC022447.4, AC022447.5, AC022447.3, AC022447.1, AC022447.7, AC022447.6, RNU6-358P, AC010469.1, RNU6-760P, AC010469.2, RPL5P14, TPT1P5, AC025458.1, MIR4279, AC025178.1, GOLPH3, Y_RNA, AC025181.2, AC025181.1, MTMR12, RNU6-1079P, RNU6-378P, ZFR, MIR579.
- chr5:134,648,785–134,855,133, 6 genes, copy number 9 (within-gene range 7–9): SEC24A, RNU6-1164P, RNU6-757P, CAMLG, DDX46, AC010301.1.
- chr7:5,526,409–5,563,902, 3 genes, copy number 10: ACTB, AC006483.2, AC006483.1.
- chr8:97,624,203–97,865,485, 8 genes, copy number 9: AP002982.1, MTDH, Y_RNA, LAPTM4B, AP003357.1, AP002906.1, SUMO2P18, RPS23P1.
- chr8:99,960,936–100,131,268, 3 genes, copy number 10: RGS22, SNORD77B, AC021590.1.
- chr15:21,927,657–21,951,323, 2 genes, copy number 15–52: NF1P2, MIR5701-3.
- chr15:22,125,511–22,152,897, 3 genes, copy number 13 (within-gene range 8–13): OR4N3P, AC010760.1, RPS8P10.
- chr16:28,494,643–28,539,008, 3 genes, copy number 9 (within-gene range 5–9): APOBR, IL27, NUPR1.
- chr16:28,548,331–28,554,140, 2 genes, copy number 9 (within-gene range 7–9): AC020765.1, AC020765.2.
- chr17:30,831,966–30,906,238, 6 genes, copy number 9: ATAD5, AC130324.2, RNU6-298P, AC130324.1, TEFM, AC130324.3.
- chr17:32,324,431–32,381,885, 6 genes, copy number 9 (within-gene range 5–9): AC005899.4, C17orf75, AC005899.3, OOSP1P2, MIR632, ZNF207.
- chr17:39,173,290–39,204,840, 3 genes, copy number 9: AC004408.1, CACNB1, RPL19.
- chr17:40,113,215–40,195,656, 6 genes, copy number 9: AC068669.1, MSL1, CASC3, MIR6866, RAPGEFL1, MIR6867.
- chr17:42,184,060–42,194,532, 2 genes, copy number 9: HCRT, GHDC.
- chr17:42,313,324–42,440,259, 3 genes, copy number 9: STAT3, CAVIN1, RNU7-97P.
- chr17:43,216,941–43,305,397, 14 genes, copy number 9 (within-gene range 6–9): CCDC200, RNU2-1, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2, U2.
- chr17:44,290,856–44,324,870, 6 genes, copy number 9: RN7SL507P, RUNDC3A-AS1, U3, RNU6-453P, RUNDC3A, SLC25A39.
- chr17:44,656,404–44,752,264, 7 genes, copy number 9: MEIOC, CCDC43, AC091152.2, AC091152.4, DBF4B, RN7SL819P, AC091152.1.
- chr17:48,956,650–48,997,492, 3 genes, copy number 9 (within-gene range 5–9): AC091133.2, GIP, AC091133.3.
- chr17:62,122,320–62,140,639, 2 genes, copy number 9: Y_RNA, POLRMTP1.
- chr17:63,454,993–63,472,093, 2 genes, copy number 9: AC005828.5, PPIAP55.
- chr17:67,717,931–67,785,293, 4 genes, copy number 10: NOL11, SNORA38B, RPSAP67, RPL17P41.
- chr18:738,058–739,662, 2 genes, copy number 9 (within-gene range 7–9): AP001020.1, AP001020.2.
- chr19:29,489,775–29,675,477, 5 genes, copy number 10 (within-gene range 7–10): AC011474.2, AC011474.4, VSTM2B, POP4, PLEKHF1.
- chr19:34,254,552–34,428,273, 8 genes, copy number 9–11: GARRE1, RPL29P33, AC010504.1, GPI, AC092073.1, PDCD2L, RN7SL154P, AC008747.1.
- chr19:35,596,581–35,964,063, 37 genes, copy number 10–14: LINC01766, AC002115.1, HAUS5, RBM42, ETV2, COX6B1, UPK1A, UPK1A-AS1, TYMSP2, ZBTB32, KMT2B, IGFLR1, AD000671.2, U2AF1L4, PSENEN, AD000671.1, AD000671.3, LIN37, AC002398.2, HSPB6, PROSER3, AC002398.1, ARHGAP33, LINC01529, PRODH2, NPHS1, KIRREL2, APLP1, RN7SL402P, NFKBID, AD000864.1, HCST, TYROBP, LRFN3, AF038458.3, AF038458.1, AF038458.2.
- chr22:18,906,028–18,947,732, 3 genes, copy number 21 (within-gene range 3–21): DGCR6, AC007326.4, PRODH.

Autosomal genes at a single copy (total copy number 1): 30. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
